Somatic mutation profile of tumor specimen 0DQHB0 from CCDI case PBCFAF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.9 years (5,809 days).
Specimen 0DQHB0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1eb3b838-032e-4e22-bcd3-c2ed7f82acfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55b0aa8e-d64d-4b9f-86d3-b6912a904440

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, 3'UTR 2, Intron 2, Splice Site 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 166/407 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 170/394 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, varscan2
- SMARCA4 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 178/432 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60785813, COSV60799159; called by muse, varscan2
- AC244197.3 | c.873G>T p.W291C | Missense Mutation (SNP) | VAF 130/414 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128208, CM983346; called by muse, varscan2
- COL5A3 | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.843); catalogued as rs200041657; called by muse, varscan2
- CTNNBIP1 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 108/276 reads (39%) | catalogued as COSV101032662; called by muse, varscan2
- GABRE | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 188/468 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150104349; called by muse, varscan2
- GAS6 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 226/488 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769599558; called by muse, varscan2
- IGF1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 217/480 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767410581; called by muse, varscan2
- KLHL17 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as rs1485826914; called by muse, varscan2
- MYH11 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1490228863, COSV55542054; ClinVar: uncertain significance; called by muse, varscan2
- NEK6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 301/646 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as rs148262318; called by muse, varscan2
- NOS1AP | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 238/615 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs540786166, COSV62640444; called by muse, varscan2
- OR9G4 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 124/396 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV57249722; called by muse, varscan2
- PKLR | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 125/325 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as CM061898, COSV104418128; called by muse, varscan2
- PRKDC | c.7564C>T p.R2522* | Nonsense Mutation (SNP) | VAF 161/369 reads (44%) | catalogued as COSV100038371; called by muse, varscan2
- SIRPB2 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 172/530 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs200528602; called by muse, varscan2
- SYNPO2 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 181/450 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs780744499, COSV61113943; called by muse, varscan2
- TPP2 | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1165306104; called by muse, varscan2
- ZAR1L | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 130/367 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs749080727; called by muse, varscan2
- AKAP7 | c.226A>G p.R76G | Missense Mutation (SNP) | VAF 62/530 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, varscan2
- CNTN6 | c.3034C>A p.L1012I | Missense Mutation (SNP) | VAF 256/604 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, varscan2
- GRIA3 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 276/576 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- NOTCH1 | c.7496G>T p.S2499I | Missense Mutation (SNP) | VAF 110/235 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, varscan2
- OR4F15 | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 207/520 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- FSTL4 | c.747C>T p.L249= | Silent (SNP) | VAF 72/614 reads (12%) | catalogued as rs1333711936; called by muse, varscan2
- KIF26A | c.3618C>A p.I1206= | Silent (SNP) | VAF 118/252 reads (47%) | catalogued as COSV59471428; called by muse, varscan2
- OR5V1 | c.139T>C p.L47= | Silent (SNP) | VAF 229/576 reads (40%) | called by muse, varscan2
- SLC6A8 | c.543C>T p.C181= | Silent (SNP) | VAF 146/372 reads (39%) | catalogued as rs1221310274, COSV53472429; ClinVar: likely benign; called by muse, varscan2
- AACS | c.-52C>T | 5'UTR (SNP) | VAF 74/184 reads (40%) | called by muse, varscan2
- CLEC4G | c.167-49G>T | Intron (SNP) | VAF 48/96 reads (50%) | called by muse, varscan2
- MMP3 | c.*84G>A | 3'UTR (SNP) | VAF 59/143 reads (41%) | catalogued as rs988630939; called by muse, varscan2
- SVOP | c.*36C>A | 3'UTR (SNP) | VAF 48/93 reads (52%) | called by muse, varscan2
- ZC3H7A | c.2214-38G>A | Intron (SNP) | VAF 19/161 reads (12%) | catalogued as rs370742014; called by muse, varscan2
